Surgical pathology report (de-identified scan), TCGA case TCGA-12-3644, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Duke, specimen TCGA-12-3644-01A (Primary Tumor).

Patient: [REDACTED]

TCGA-12-3644

AP Surgical Pathology: Final [REDACTED] Acc# [REDACTED]

Surg Path

CLINICAL HISTORY:

Right temporal parietal brain tumor. History of malignant astrocytoma.

GROSS EXAMINATION:

A. "Brain tissue (AF1)". Received fresh for frozen section is a 1.3 x 0.5 x 0.3 cm fragment of red-tan tissue. Representative is frozen as AF1, the frozen remnant in block A1. A small fragment is retained in formalin and the remaining tissue is submitted in block A2.

INTRA OPERATIVE CONSULTATION:

A. "Brain tissue": AF1-anaplastic glioma [REDACTED]

MICROSCOPIC EXAMINATION:

The tissue is brain infiltrated by small cell anaplastic glial neoplasm characterized by vascular proliferation regions of necrosis.

DIAGNOSIS:

A. "RIGHT TEMPORAL PARIETAL BRAIN TUMOR":

GLIOBLASTOMA (WHO GRADE IV).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
Electronically signed: [REDACTED]

Source: NCI Genomic Data Commons file 7fa4f688-c605-4921-9fbe-eb73e9a47a3e (TCGA-12-3644.12A77F13-7940-4D58-AD15-F598C89F6A08.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).